Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD2-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, hepatocellular NOS
Site Liver C&A.O
8170/3
QW 5/19/14

CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen:

Liver: 11.0 x 9.0 x 4.8 cm, 170.5 gm, fresh

Tumor location: Segment 2

Tumor number: One

Tumor size: 3.0 x 2.8 x 2.2 cm

Gross type:

HCC: Nodular

Tumor necrosis: No

Hemorrhage/peliosis: No

Portal vein invasion: No

Bile duct invasion: No

External surface: Grossly not involved

Gross photo: Present

Blocks

T1-4, tumor mass x 4

RM, resection margin x 1

L, non-tumorous liver parenchyme x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

Differentiation

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No, partial capsule

Septum formation: No

Surgical resection margin invasion:

No - close to the tumor mass: less than 0.2 cm

Serosal invasion: No

Portal vein invasion: No

Bile duct invasion: No

Hepatic vein invasion: No

Hepatic artery invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: No

Multicentric occurrence: No

Non-tumor liver pathology

[page 2 of 2]
Chronic hepatitis: Yes
Etiology: HBV
Grade, lobular: Minimal
Grade, portoperiportal: Minimal
Stage (fibrosis): Portal
Cirrhosis: No
Dysplastic nodule: No
Ductal epithelial dysplasia: No
Other liver diseases: No

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

DIGNOSIS: Liver, segment 2, lobectomy:
Hepatocellular carcinoma, well differentiated

Suggestion :

Source: NCI Genomic Data Commons file bec6e04e-d121-4d02-9025-463729d80a8b (TCGA-DD-AAD2.3F50DE59-F830-4D51-90C6-7B275AF0876F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).